Surgical pathology report (de-identified scan), TCGA case TCGA-DI-A1BY, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site MD Anderson, specimen TCGA-DI-A1BY-01A (Primary Tumor).

[page 1 of 3]
Specimen Date/Time:

***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

(A) PANNUS, EXCISION:
Skin and underlying adipose tissue, with no pathologic changes.

(B) UTERUS, BILATERAL OVARIES AND FALLOPIAN TUBES:
ENDOMETRIOID ENDOMETRIAL ADENOCARCINOMA, GRADE 2.
CARCINOMA INVADES 0.4 CM WITH 2.3 CM MYOMETRIAL THICKNESS.
CARCINOMA INVOLVES ENDOCERVICAL GLANDS AND STROMA (0.3 CM WITH 1.7 CM
CERVICAL THICKNESS).

No lymphovascular invasion identified.
Squamous mucosa, negative for carcinoma.
Right ovary with simple cysts.
Right fallopian tube, no tumor present.
Left ovary with no pathologic changes.
Left fallopian tube with paratubal cysts.

(C) RIGHT PELVIC LYMPH NODES:
Three lymph nodes, no tumor present (0/3).

(D) OMENTUM:
Fibroadipose tissue, no tumor present.

(E) LEFT PELVIC LYMPH NODES:
Three lymph nodes, no tumor present (0/3).

(F) UMBILICUS:
Fibroadipose tissue, no tumor present.

105-0-3
Adenocarcinoma, Endometrioid, NOS 8380/3
Site Code: Endometrium C54.1
1/2/11
lu

Entire report and diagnosis completed by

GROSS DESCRIPTION

(A) PANNUS - Consists of pannus excision specimen, 98 x 8 cm, excised to a depth of 11 cm and 110 cm x 15 cm, excised to a depth of 11 cm. Serially sectioned to unremarkable fibroadipose tissue throughout. The skin is unremarkable. Representatively submitted in A1 and A2.

(B) UTERUS, CERVIX, BILATERAL TUBES AND BILATERAL OVARIES - A total hysterectomy with uterus (13.1 x 8.3 x 3.2 cm) and attached cervix (3.2 cm in diameter). Also received are the right and left ovaries and fallopian tubes. Ovaries are 2.8 x 2.0 x 1.0 cm and fallopian tubes are 3.0 cm in length x 0.5 cm in diameter.

Within the endometrial cavity is a large fungating tumor that entirely replaces the endometrium and measures 10.9 x 9.5 cm. It is 0.6 cm in thickness. The maximal myometrial thickness is 3.6 cm. The tumor approaches the left isthmus area. The tumor also extends into the lower uterine segment and into the cervix.

The right and left ovaries are grossly unremarkable. The right fallopian tube is grossly unremarkable. The left fallopian tube has several benign paratubal cysts.

SECTION CODE: B1, B2, tumor, full thickness, frozen section; B3, B4, tumor, full thickness section; B5, B6, tumor with cervix, frozen section; B7-B12, anterior endomyometrium, full thickness with corresponding serosa; B13-B16, posterior endomyometrium, full thickness with corresponding serosa; B17, representative section of tumor; B18, representative section of tumor with isthmus; B19, B20, additional sections of tumor; B21, anterior cervix; B22, posterior lower uterine segment; B23, posterior cervix; B24, right ovary; B25, right fallopian tube; B26, left ovary; B27, left fallopian tube.

*FS/DX: ENDOMETRIOID, ENDOMETRIOID ADENOCARCINOMA, FIGO GRADE 2, INVADING 5.0 MM INTO 27

[page 2 of 3]
MM THICK MYOMETRIUM; TUMOR GROSSLY INTO ENDOCERVIX, ON SLIDE IS LOWER UTERINE SEGMENT.

(C) RIGHT PELVIC LYMPH NODE - Multiple pieces of yellow soft tissue measuring 6.0 x 5.0 x 2.0 cm in aggregate. Multiple nodes identified with the largest fatty node measuring 3.5 cm in greatest dimension and entirely submitted as following: C1-C3, one possible fatty node, serially sectioned; C4-C5, one possible fatty node, serially sectioned; C6, C7, one possible fatty node, serially sectioned.

(D) OMENTUM BIOPSY - One piece of yellow soft tissue (6.0 x 4.0 x 1.0 cm). Serial sectioning reveals no grossly identified lesion. Representative section submitted in cassette D1-D3.

(E) LEFT PELVIC LYMPH NODE - Four pieces of yellow soft tissue measuring 4.0 x 3.0 x 1.0 cm in aggregate with the largest 2.5 cm. Multiple nodes identified with the largest one measuring 2.0 cm and entirely submitted as following: E1, E2, largest possible fatty node, serially sectioned; E3, three possible nodes.

(F) UMBILICUS - One piece of yellow soft tissue measuring 5.5 x 4.5 x 3.0 cm which one side has a smooth membranous lining associated with focal hemorrhage. Serial sectioning revealed irregular-shaped, tan-white, fibrotic tissue underneath the membranous lining with focal hemorrhage. No definitive lesion is grossly identified. Representative sections are submitted in F1-F3.

CLINICAL HISTORY

Abdominal panniculus/uterine cancer.

SNOMED CODES

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

. These tests have not been

Entire report and diagnosis completed by:

Start of ADDENDUM

[page 3 of 3]
ADDENDUM

This modified report is being issued to provide additional information/results.

Addendum completed by

(C) RIGHT PELVIC LYMPH NODES:
Eight lymph nodes, no tumor present (0/8)

COMMENT

Five additional lymph nodes are identified.

GROSS DESCRIPTION

The remaining fatty tissue in part C is submitted for microscopic examination.

(C) RIGHT PELVIC LYMPH NODES -
SECTION CODE: C8-C13, the rest of the fatty tissue. Note: The specimen is entirely submitted.

Entire report and diagnosis completed by: I

-----END OF REPORT-----

Source: NCI Genomic Data Commons file 3191d3e5-d503-44a7-b59a-548bf9fb19b7 (TCGA-DI-A1BY.8B96371D-5E42-461B-B7A2-AB9641D842CD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).